Gene-level copy-number profile of tumor specimen TCGA-C5-A2LY-01A from TCGA case TCGA-C5-A2LY, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 30.2 years (11,018 days).
Specimen TCGA-C5-A2LY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.c715d2b5-085e-4175-b9ea-b9649b3535e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A2LY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d423ed88-f7f2-43f7-a37a-3bd058008131

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,452; copy number 2: 40,485; copy number 3: 13,808; copy number 4: 3; copy number 5: 330; copy number 6: 156; copy number 7: 1,300; copy number 9: 57; copy number 10: 15; copy number 11: 65; copy number 15: 21; copy number 19: 5; copy number 23: 58; copy number 33: 5; copy number 34: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A2LY-01A-31D-A18H-01): tumor purity 0.63, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,070 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–119,473,803, 21 genes, copy number 6: PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1.
- chr2:211,375,717–212,538,841, 1 gene, copy number 5 (within-gene range 3–5): ERBB4.
- chr2:212,426,263–219,737,937, 189 genes, copy number 5 (broad region; genes not listed).
- chr2:238,412,642–242,160,153, 107 genes, copy number 5 (broad region; genes not listed).
- chr3:120,164,645–198,222,513, 1,435 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:101,029,624–104,682,581, 63 genes, copy number 19–34 (broad region; genes not listed).
- chr12:990,509–1,918,666, 15 genes, copy number 10 (within-gene range 1–10): ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2.
- chr12:8,014,093–8,242,948, 21 genes, copy number 15: AC006511.4, HSPD1P12, AC006511.2, FOXJ2, C3AR1, NECAP1, AC006511.3, AC006511.5, CLEC4A, POU5F1P3, AC092111.3, GCSHP4, ZNF705A, FAM66C, DEFB109F, AC092111.2, AC092111.1, FAM90A1, ALG1L10P, FAM86FP, LINC02449.
- chr18:3,190,397–7,461,135, 78 genes, copy number 11–33 (broad region; genes not listed).
- chr19:12,664,828–15,145,318, 140 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,452. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
